Somatic mutation profile of tumor specimen TCGA-EE-A29M-06A (aliquot TCGA-EE-A29M-06A-11D-A196-08) from TCGA case TCGA-EE-A29M, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 35.2 years (12,874 days).
Specimen TCGA-EE-A29M-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c02b21b8-ce62-4d98-a4d7-fd34f2139b33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29M-10A (Blood Derived Normal), aliquot TCGA-EE-A29M-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61e4951b-fce7-4db8-8b68-29f3f8e06c77

The open-access MAF lists 2,830 somatic variants for this specimen: 1,853 protein-altering or splice-affecting, 900 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,714, Silent 900, Nonsense Mutation 82, RNA 32, Intron 26, Splice Site 24, Splice Region 20, Frame Shift Del 9, 3'UTR 6, 3'Flank 6, 5'UTR 4, 5'Flank 3.

Variants (750 of 2,830; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL2A1 | c.141G>A p.W47* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs121912896, CM002756, COSV61534196; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A4 | c.1696+1G>A p.X566_splice | Splice Site (SNP) | VAF 48/186 reads (26%) | catalogued as rs954701825, COSV61636467; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852373, CM910138, COSV64278526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NCR1 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 69/183 reads (38%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52558473; called by muse, mutect2, varscan2
- PHKG2 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as rs137853590, CM981537, COSV60313760, COSV60313919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs199473062, CM023671, CM100631; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.400T>C p.F134L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267605077, COSV52660909, COSV52676112, COSV52697695, COSV52923862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPP1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908205, CM011757, COSV54995332; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WDR35 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs199840434, COSV55606819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1229G>A p.G410E (on ENST00000373993 / NM_138932.2; = p.G402E on NM_014576.4) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.357); catalogued as COSV50983741, COSV50992038; called by muse, mutect2, varscan2
- A1CF | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV50957573; called by muse, mutect2, varscan2
- AADAC | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51761363; called by muse, mutect2, varscan2
- ABCA12 | c.2419G>A p.G807R (on ENST00000272895 / NM_173076.3; = p.G489R on NM_015657.3) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55975006; called by muse, mutect2, varscan2
- ABCA13 | c.12029C>T p.S4010F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310173250, COSV71294060, COSV71295347; called by muse, mutect2, varscan2
- ABCA2 | c.2162C>T p.P721L (on ENST00000614293; = p.P691L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55806628, COSV99687786; called by muse, mutect2, varscan2
- ABCA2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV55806632; called by muse, mutect2, varscan2
- ABCA4 | c.5726C>T p.P1909L | Missense Mutation (SNP) | VAF 147/303 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV64677913; called by muse, mutect2, varscan2
- ABCA7 | c.4027C>T p.P1343S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54037183; called by muse, mutect2, varscan2
- ABCB1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963240, COSV99713274; called by muse, mutect2, varscan2
- ABCB10 | c.538A>T p.M180L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60623737; called by muse, mutect2, varscan2
- ABCB5 | c.2020C>T p.P674S (on ENST00000404938 / NM_001163941.2; = p.P229S on NM_178559.6) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs763265331, COSV51705510; called by muse, mutect2, varscan2
- ABCB5 | c.2413A>T p.I805F (on ENST00000404938 / NM_001163941.2; = p.I360F on NM_178559.6) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV51720499; called by muse, mutect2, varscan2
- ABCC1 | c.536T>A p.F179Y | Missense Mutation (SNP) | VAF 83/498 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1358279091, COSV60693811; called by muse, mutect2, varscan2
- ABCC9 | c.4371T>A p.F1457L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV53985513; called by muse, mutect2, varscan2
- ABCC9 | c.3329C>T p.T1110I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53985530; called by muse, mutect2, varscan2
- ABHD2 | c.1001A>C p.Y334S | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61773394, COSV61776117; called by muse, mutect2, varscan2
- ABO | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1039737787, COSV71743679; called by muse, mutect2, varscan2
- AC008397.2 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53204706, COSV53209646; called by muse, mutect2, varscan2
- AC100868.1 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV51849771; called by muse, mutect2
- ACD | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs868651125, COSV54666888; called by muse, mutect2, varscan2
- ACO1 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV59384810; called by muse, mutect2, varscan2
- ACOT12 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56898038; called by muse, mutect2, varscan2
- ACOT4 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV58335659; called by muse, mutect2, varscan2
- ACOXL | c.1429G>A p.A477T (on ENST00000389811 / NM_001371254.1; = p.A447T on NM_001142807.4) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs373938336, COSV67735541; called by muse, varscan2
- ACSBG1 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 171/560 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51910864; called by muse, mutect2, varscan2
- ACSL5 | c.157-2A>T p.X53_splice (on ENST00000354273; = p.X109_splice on NM_016234.3) | Splice Site (SNP) | VAF 36/94 reads (38%) | catalogued as COSV61133416; called by muse, mutect2, varscan2
- ACSM2B | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 37/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61657166; called by muse, mutect2
- ACSM2B | c.423A>T p.K141N | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV61659918; called by muse, mutect2, varscan2
- ACSS2 | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53628317; called by muse, mutect2, varscan2
- ACTL8 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1360889975, COSV64862667; called by muse, mutect2, varscan2
- ACTN1 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51997434; called by muse, mutect2, varscan2
- ACTRT2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 56/249 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as COSV101007438, COSV65760464; called by muse, mutect2, varscan2
- ACVRL1 | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as CM050025, CM051838, COSV66361088; called by muse, mutect2, varscan2
- ADAM22 | c.2510G>A p.G837D | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55989972; called by muse, mutect2, varscan2
- ADAM28 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765204427, COSV56102242, COSV56105258; called by mutect2, varscan2
- ADAM33 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV62936875; called by muse, mutect2, varscan2
- ADAM7 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs777631956, COSV51535626; called by muse, mutect2, varscan2
- ADAMTS13 | c.3191G>A p.S1064N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.287); catalogued as COSV63023101; called by muse, varscan2
- ADAMTS17 | c.3175C>T p.R1059W | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201387097; called by muse, mutect2, varscan2
- ADAMTS18 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs774605827, COSV51422948; called by muse, mutect2, varscan2
- ADAMTS18 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770516167, COSV51399705; called by muse, mutect2, varscan2
- ADAMTS20 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.177); catalogued as COSV67139093; called by muse, mutect2, varscan2
- ADAMTS6 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV58685118; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs955825788; called by muse, mutect2, varscan2
- ADAP1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV56217348, COSV56217698; called by muse, mutect2, varscan2
- ADCY1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as COSV52037613; called by muse, mutect2, varscan2
- ADCY1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV52042313; called by muse, mutect2, varscan2
- ADCY10 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as rs760410331, COSV63238359; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as rs1476693224, COSV58446664; called by muse, mutect2, varscan2
- ADGRB3 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.883); catalogued as COSV101000613, COSV65419040; called by muse, mutect2, varscan2
- ADGRE1 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.558); catalogued as COSV51671968; called by muse, mutect2, varscan2
- ADGRE1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1269731726, COSV51676242; called by muse, mutect2, varscan2
- ADGRF2 | c.1898C>T p.A633V (on ENST00000296862 / NM_001368115.2; = p.A565V on NM_153839.7) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV57291878; called by muse, mutect2, varscan2
- ADGRL4 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV66065805; called by muse, mutect2, varscan2
- ADGRV1 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV67995129; called by muse, mutect2, varscan2
- ADH5 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV56449081; called by muse, mutect2, varscan2
- ADH6 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs865936658, COSV52957868; called by muse, mutect2, varscan2
- ADRA2B | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1393193986, COSV69788315; called by muse, mutect2, varscan2
- ADRA2B | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as COSV69788319; called by muse, mutect2, varscan2
- AFM | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs531634253, COSV56919726; called by muse, mutect2, varscan2
- AGAP2 | c.2000G>A p.G667E (on ENST00000547588 / NM_001122772.2; = p.G331E on NM_014770.4) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57731614; called by muse, mutect2, varscan2
- AGBL1 | c.2603C>T p.S868F | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV66872357; called by muse, mutect2, varscan2
- AGTR2 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV64157038; called by muse, varscan2
- AHNAK | c.10247C>T p.S3416F | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759345932, COSV57229837; called by muse, mutect2, varscan2
- AJAP1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65454318; called by muse, varscan2
- AKAP12 | c.2125G>A p.G709R | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); catalogued as COSV53581906; called by muse, mutect2, varscan2
- AKAP4 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62075439; called by muse, mutect2, varscan2
- AKAP4 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV62075444; called by muse, mutect2, varscan2
- AL645922.1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191402; called by muse, mutect2, varscan2
- AL645922.1 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.674); catalogued as COSV64888492; called by muse, mutect2, varscan2
- ALDH1L1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV56419204; called by muse, mutect2, varscan2
- ALOX12B | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1393418105, COSV59876314; called by muse, mutect2, varscan2
- ALOX15B | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV101205688; called by muse, mutect2, varscan2
- ALPI | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV55016131; called by muse, varscan2
- ALPI | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99786105; called by muse, varscan2
- AMER3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs764045425, COSV58465777; called by muse, mutect2, varscan2
- AMIGO1 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 118/570 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63990601; called by muse, mutect2, varscan2
- AMPD1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.392); catalogued as COSV62418903; called by muse, mutect2, varscan2
- AMPD1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 111/265 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV62416345; called by muse, mutect2, varscan2
- AMY1C | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 76/570 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757570508, COSV100915232; called by muse, mutect2, varscan2
- ANAPC4 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1450004796, COSV59543235; called by muse, mutect2, varscan2
- ANAPC7 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as COSV71444055; called by muse, mutect2, varscan2
- ANK2 | c.5035G>A p.G1679R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as COSV52187926; called by muse, mutect2, varscan2
- ANK3 | c.9208C>T p.P3070S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55080772; called by muse, mutect2, varscan2
- ANKRD50 | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV72386296; called by muse, mutect2, varscan2
- ANKS1B | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.994); catalogued as rs771639722, COSV59124493; called by muse, mutect2, varscan2
- ANKS1B | c.2621C>T p.P874L (on ENST00000547776 / NM_152788.4; = p.P100L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60375063; called by muse, mutect2
- ANKS1B | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV61375464; called by muse, mutect2, varscan2
- ANO2 | c.1304C>T p.P435L (on ENST00000356134 / NM_001278597.3; = p.P439L on NM_001278596.3) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV59016007, COSV59042820; called by muse, mutect2, varscan2
- ANO4 | c.869C>T p.S290F (on ENST00000392977 / NM_001286615.2; = p.S255F on NM_178826.4) | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV54612980; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANXA10 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV63740390; called by muse, mutect2, varscan2
- AOPEP | c.1882C>T p.Q628* (on ENST00000375315 / NM_001193329.1; = p.Q529* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as COSV52998839; called by muse, mutect2, varscan2
- AP2B1 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV52003431; called by muse, mutect2, varscan2
- AP3B2 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs34200105; called by muse, mutect2, varscan2
- AP5M1 | c.1157T>C p.L386S | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55106925; called by muse, mutect2, varscan2
- APOB | c.9851C>T p.S3284F | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV51951697; called by muse, mutect2, varscan2
- APOH | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV52771276, COSV52774973; called by muse, mutect2, varscan2
- APOL5 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV50768499; called by muse, mutect2, varscan2
- AQP6 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59646912; called by muse, mutect2, varscan2
- ARAP1 | c.3303G>A p.M1101I (on ENST00000393609 / NM_001040118.2; = p.M856I on NM_015242.4) | Missense Mutation (SNP) | VAF 193/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61994909; called by muse, mutect2, varscan2
- ARAP2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58286815; called by muse, mutect2, varscan2
- ARAP2 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268831523, COSV100395126; called by muse, mutect2, varscan2
- ARHGAP11A | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64381646; called by muse, mutect2, varscan2
- ARHGAP30 | c.2969G>A p.R990K (on ENST00000368013 / NM_001025598.2; = p.R779K on NM_181720.3) | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs374307651, COSV63519275; called by muse, mutect2, varscan2
- ARHGAP30 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 114/344 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.381); catalogued as rs534430037, COSV63519285; called by muse, mutect2, varscan2
- ARHGAP30 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 157/680 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs759817018, COSV63519294; called by muse, mutect2, varscan2
- ARHGAP31 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51798776; called by muse, mutect2, varscan2
- ARHGAP36 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52271725; called by muse, varscan2
- ARHGEF10 | c.1633C>A p.Q545K (on ENST00000398564; = p.Q520K on NM_014629.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.524); catalogued as COSV50677021; called by muse, varscan2
- ARHGEF10L | c.3671G>A p.R1224Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs528120584, COSV51440277; called by muse, mutect2, varscan2
- ARHGEF2 | c.551C>T p.T184I (on ENST00000361247 / NM_001162383.2; = p.T157I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV58117002; called by muse, mutect2, varscan2
- ARHGEF28 | c.3448G>A p.E1150K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55269888; called by muse, mutect2, varscan2
- ARHGEF5 | c.4559C>T p.A1520V | Missense Mutation (SNP) | VAF 101/365 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50218972; called by muse, mutect2, varscan2
- ARID4B | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.284); catalogued as COSV51611064; called by muse, mutect2, varscan2
- ARID5A | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100673635; called by muse, mutect2, varscan2
- ARMC1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV52534815; called by muse, mutect2, varscan2
- ARMCX5 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1213364116, COSV55767599; called by muse, mutect2, varscan2
- ARMH4 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs753724463, COSV50773505; called by muse, mutect2, varscan2
- ARPP21 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs867786211, COSV51807889; called by muse, mutect2, varscan2
- ASAP2 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV55638512; called by muse, mutect2, varscan2
- ASIC5 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72232548; called by muse, mutect2
- ASPM | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54138439; called by muse, mutect2, varscan2
- ASPSCR1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201786107, COSV60729183; called by muse, mutect2, varscan2
- ASTL | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60905396; called by muse, mutect2, varscan2
- ASTN2 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as rs1252608085, COSV57816796; called by muse, mutect2, varscan2
- ASTN2 | c.443-1G>A p.X148_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57750143, COSV57816830; called by muse, varscan2
- ASXL3 | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 161/359 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52479097; called by muse, mutect2, varscan2
- ASXL3 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV52465337; called by muse, mutect2, varscan2
- ATAD3B | c.323C>T p.S108F (on ENST00000308647; = p.S162F on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs145500839; called by muse, mutect2, varscan2
- ATAD3B | c.344C>T p.T115I (on ENST00000308647; = p.T221I on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs1158117775, COSV58023310; called by muse, mutect2, varscan2
- ATF7IP | c.3760C>T p.P1254S | Missense Mutation (SNP) | VAF 65/338 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); catalogued as COSV53777484; called by muse, mutect2, varscan2
- ATG2A | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65968852; called by muse, mutect2
- ATL2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as rs371444918; called by muse, mutect2, varscan2
- ATP13A5 | c.2034-1G>A p.X678_splice | Splice Site (SNP) | VAF 50/122 reads (41%) | catalogued as rs138259240, COSV60875263; called by muse, mutect2, varscan2
- ATP13A5 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.544); catalogued as COSV60875277; called by muse, mutect2, varscan2
- ATP1A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 129/377 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63405819; called by muse, mutect2, varscan2
- ATP2B2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761073766, COSV59507224; called by muse, mutect2, varscan2
- ATP2B4 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58183694; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 99/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52877824; called by muse, mutect2, varscan2
- AXDND1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs371568732, COSV62639980; called by muse, mutect2, varscan2
- B3GALT6 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV55417328; called by muse, mutect2, varscan2
- B3GNT3 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV59438921; called by muse, mutect2, varscan2
- B4GALT4 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1325577449, COSV100785841; called by muse, mutect2, varscan2
- BAAT | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs765307307, COSV52290986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAHCC1 | c.5912C>T p.S1971F | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57033090; called by muse, mutect2, varscan2
- BAHD1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV69084722; called by muse, mutect2, varscan2
- BAZ1A | c.3520C>T p.H1174Y | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62412142; called by muse, mutect2, varscan2
- BAZ2A | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51643550; called by muse, mutect2, varscan2
- BCAS1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1215590959, COSV65089273; called by muse, mutect2, varscan2
- BCL2L2-PABPN1 | c.1088C>T p.S363F (on ENST00000678502; = p.S331F on NM_001199864.2) | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.091); catalogued as COSV99391251; called by muse, mutect2, varscan2
- BCL7C | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.469); catalogued as COSV53064363; called by muse, mutect2, varscan2
- BEND2 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as COSV66217234; called by muse, mutect2, varscan2
- BEND2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV66215132; called by muse, mutect2, varscan2
- BICD1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160828139, COSV55688040; called by muse, mutect2, varscan2
- BICD1 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.269); catalogued as COSV55682178, COSV55688053; called by muse, mutect2, varscan2
- BICRAL | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58407449; called by muse, mutect2, varscan2
- BIN2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57203584; called by muse, mutect2, varscan2
- BMP10 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54897081; called by muse, mutect2, varscan2
- BMP8A | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59034203; called by muse, mutect2, varscan2
- BMP8B | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100735482; called by muse, mutect2
- BPTF | c.6686C>T p.S2229F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58846494; called by muse, mutect2, varscan2
- BRDT | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV62864260; called by muse, mutect2, varscan2
- BRINP2 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100838125, COSV64178579; called by muse, mutect2, varscan2
- BRINP2 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64180139; called by muse, mutect2, varscan2
- BRINP2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762582867, COSV64180145; called by muse, mutect2, varscan2
- BRINP3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.953); catalogued as rs774992892, COSV66540980; called by muse, mutect2, varscan2
- BRINP3 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.086); catalogued as COSV100818385, COSV66540992; called by muse, mutect2, varscan2
- BSND | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV64871379; called by muse, varscan2
- BSX | c.264G>A p.G88= | Splice Region (SNP) | VAF 28/76 reads (37%) | catalogued as rs769363288, COSV58006260; called by muse, mutect2, varscan2
- BTN2A1 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV57006258; called by muse, mutect2, varscan2
- BTNL2 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 98/369 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1382825467, COSV66631867; called by muse, mutect2, varscan2
- BTNL3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1468570079, COSV61564583; called by muse, varscan2
- C12orf40 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs1437918956, COSV61137632; called by muse, mutect2, varscan2
- C12orf50 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs757520062, COSV53898848; called by muse, mutect2, varscan2
- C14orf28 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57334182; called by muse, mutect2, varscan2
- C14orf39 | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58785020; called by muse, mutect2, varscan2
- C15orf39 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV62298173; called by muse, mutect2, varscan2
- C16orf89 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301302453, COSV60122446; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, mutect2, varscan2
- C1QTNF9B | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1463638854, COSV65943913; called by mutect2, varscan2
- C1orf210 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs748839312, COSV70682522, COSV70682563; called by muse, mutect2, varscan2
- C2CD3 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58100759; called by muse, mutect2, varscan2
- C3 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 117/440 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.182); catalogued as rs769034459, COSV55581213; called by muse, mutect2, varscan2
- C4B | c.3823C>T p.H1275Y | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV70313300; called by mutect2, varscan2
- C6 | c.2546G>A p.R849K | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54706968; called by muse, varscan2
- C7 | c.1766T>A p.F589Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV57480722; called by muse, varscan2
- C7 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs368055535; called by muse, mutect2, varscan2
- C8B | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs761533195, COSV64777481; called by muse, mutect2, varscan2
- CACNA1A | c.4615G>A p.D1539N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1278971715, COSV64212123; called by muse, mutect2
- CACNA1E | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1247888338, COSV62388762; called by muse, mutect2, varscan2
- CACNA1E | c.4794G>A p.W1598* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV62413727, COSV62420417; called by muse, mutect2, varscan2
- CACNA1G | c.5675G>A p.W1892* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100661400, COSV61739093; called by muse, mutect2, varscan2
- CACNA1G | c.5807C>T p.S1936F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61720558; called by muse, mutect2, varscan2
- CACNA1H | c.6641C>T p.T2214I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV52358254; called by muse, mutect2
- CACNA1H | c.6764C>T p.S2255F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as rs746214213, COSV52358267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1I | c.4441C>T p.H1481Y | Missense Mutation (SNP) | VAF 82/430 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV60818383; called by muse, varscan2
- CACNG2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 155/697 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55640895; called by muse, mutect2, varscan2
- CACNG3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1204864111, COSV50065422; called by muse, mutect2, varscan2
- CADPS | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99340200; called by muse, mutect2, varscan2
- CALCRL | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV66477399; called by muse, mutect2, varscan2
- CAMLG | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV51805711; called by muse, mutect2
- CAMSAP2 | c.3131C>T p.S1044F (on ENST00000236925 / NM_001297707.2; = p.S1033F on NM_203459.3) | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV52677179; called by muse, mutect2, varscan2
- CAMSAP3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV50333729, COSV50364595; called by muse, mutect2, varscan2
- CAMSAP3 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.322); catalogued as rs1166759177, COSV50364955, COSV99350646; called by muse, mutect2, varscan2
- CAPN13 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as rs866528018, COSV54433200; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CASD1 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV51975421; called by muse, mutect2, varscan2
- CASP8 | c.982G>A p.G328R (on ENST00000432109 / NM_033355.3; = p.G345R on NM_001228.4) | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51859347; called by muse, mutect2, varscan2
- CASQ1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1185001392, COSV63624534, COSV99058473; called by muse, mutect2, varscan2
- CASR | c.1492G>A p.D498N (on ENST00000490131; = p.D575N on NM_000388.4) | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56141374; called by muse, mutect2, varscan2
- CASR | c.2380G>A p.E794K (on ENST00000490131; = p.E871K on NM_000388.4) | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV56141379; called by muse, mutect2, varscan2
- CASS4 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV64385591; called by muse, mutect2, varscan2
- CAT | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53813237; called by muse, mutect2, varscan2
- CATSPERD | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 79/305 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67537256; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2, varscan2
- CC2D2A | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67505542; called by muse, mutect2, varscan2
- CCDC102B | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs200230135; called by muse, mutect2, varscan2
- CCDC148 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51770349; called by muse, mutect2, varscan2
- CCDC158 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV66357175; called by muse, mutect2, varscan2
- CCDC178 | c.2326A>G p.N776D (on ENST00000383096 / NM_001105528.3; = p.N738D on NM_198995.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.472); catalogued as COSV55796716; called by muse, mutect2, varscan2
- CCDC186 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1369010535, COSV65160972; called by muse, mutect2, varscan2
- CCDC39 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV56493480; called by muse, mutect2
- CCDC60 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59547479; called by muse, varscan2
- CCDC60 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100555528; called by muse, mutect2, varscan2
- CCDC60 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100555529; called by muse, varscan2
- CCDC63 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV57531049; called by muse, mutect2, varscan2
- CCKBR | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs746523028, COSV58102335, COSV58105140; called by muse, mutect2, varscan2
- CCL24 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV56116582; called by muse, mutect2, varscan2
- CCN4 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51535648; called by muse, mutect2, varscan2
- CD163 | c.3333G>A p.M1111I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs868449455, COSV63137008; called by muse, mutect2, varscan2
- CD163 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63137014; called by muse, mutect2, varscan2
- CD163 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs1472188539, COSV63135537, COSV63137020; called by muse, mutect2, varscan2
- CD163L1 | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.702); catalogued as COSV58024364; called by muse, mutect2, varscan2
- CD1C | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 115/607 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs763083931, COSV63807005, COSV63807643; called by muse, mutect2, varscan2
- CD200R1 | c.430G>A p.G144R (on ENST00000471858 / NM_170780.3; = p.G167R on NM_138806.4) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.962); catalogued as rs866513759, COSV55602211, COSV55604027; called by muse, mutect2, varscan2
- CD300C | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58171425; called by muse, mutect2, varscan2
- CD4 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50595777; called by muse, mutect2, varscan2
- CD55 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58578087; called by muse, mutect2, varscan2
- CD96 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748781352, COSV51922835; called by muse, mutect2, varscan2
- CD96 | c.793G>A p.V265I (on ENST00000283285 / NM_198196.3; = p.V249I on NM_005816.5) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV51917161; called by muse, mutect2, varscan2
- CD96 | c.1129C>T p.L377F (on ENST00000283285 / NM_198196.3; = p.L361F on NM_005816.5) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51919040, COSV51922856; called by muse, mutect2, varscan2
- CDC42EP2 | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.216); catalogued as COSV99659187; called by muse, mutect2, varscan2
- CDC42EP4 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV59964203; called by muse, mutect2, varscan2
- CDCP1 | c.741T>G p.D247E | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56108004; called by muse, mutect2, varscan2
- CDH12 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66399725, COSV66446847, COSV66457543; called by muse, mutect2, varscan2
- CDH18 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as rs866875588, COSV56959856; called by muse, varscan2
- CDH18 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV56949614; called by muse, varscan2
- CDH23 | c.3451C>T p.R1151W | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs757628798, COSV56458136; called by muse, mutect2, varscan2
- CDH26 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54854568; called by muse, mutect2, varscan2
- CDH6 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54078121; called by muse, mutect2, varscan2
- CDH8 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54899223, COSV54903049; called by muse, varscan2
- CDH8 | c.1416G>A p.R472= | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as COSV54872649; called by muse, varscan2
- CDH8 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as COSV100183657, COSV54859342; called by muse, varscan2
- CDH8 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs1225853270, COSV54860810; called by muse, mutect2, varscan2
- CDH9 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50250776, COSV50334530; called by muse, mutect2, varscan2
- CDS1 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55690751; called by muse, mutect2, varscan2
- CEACAM20 | c.1516A>G p.S506G | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.249); catalogued as COSV57603256; called by muse, varscan2
- CEACAM20 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV57603264; called by muse, mutect2, varscan2
- CEACAM21 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV51816505; called by muse, mutect2, varscan2
- CEBPZ | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV52208415; called by muse, mutect2, varscan2
- CEP128 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374700489, COSV53673641; called by muse, varscan2
- CEP70 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 96/419 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53878331; called by muse, mutect2, varscan2
- CEP70 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 115/321 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53878343; called by muse, mutect2, varscan2
- CES1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303781942, COSV100828771; called by muse, mutect2, varscan2
- CES5A | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV51870560; called by muse, mutect2, varscan2
- CETP | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52364323; called by muse, mutect2, varscan2
- CFAP100 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs1157982358, COSV61504574; called by muse, mutect2, varscan2
- CFAP45 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63651068; called by muse, mutect2, varscan2
- CFAP47 | c.4921C>T p.Q1641* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV57976579, COSV57976699; called by muse, mutect2
- CFAP53 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV68351975; called by muse, mutect2, varscan2
- CFAP53 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 119/278 reads (43%) | catalogued as rs763985843, COSV68352878; called by muse, mutect2, varscan2
- CFAP54 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1193141126, COSV61573134; called by muse, mutect2, varscan2
- CFAP57 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV65265749; called by muse, mutect2, varscan2
- CFAP77 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58016908; called by muse, mutect2, varscan2
- CFHR2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.621); catalogued as COSV66382210; called by muse, mutect2, varscan2
- CFTR | c.2490G>A p.K830= | Splice Region (SNP) | VAF 28/112 reads (25%) | catalogued as COSV50097604; called by muse, mutect2, varscan2
- CGNL1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs781183314, COSV55572111; called by muse, mutect2, varscan2
- CHCHD1 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV65708659; called by muse, mutect2, varscan2
- CHD5 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52424580; called by muse, mutect2, varscan2
- CHD8 | c.5581C>T p.P1861S (on ENST00000646647 / NM_001170629.2; = p.P1582S on NM_020920.4) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV63037324, COSV63037461; called by muse, mutect2, varscan2
- CHD8 | c.1610C>T p.T537I (on ENST00000646647 / NM_001170629.2; = p.T258I on NM_020920.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); catalogued as COSV101303188; called by muse, mutect2, varscan2
- CHD8 | c.1609A>C p.T537P (on ENST00000646647 / NM_001170629.2; = p.T258P on NM_020920.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV101303190; called by muse, mutect2
- CHI3L1 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 46/180 reads (26%) | catalogued as COSV99704108; called by muse, mutect2, varscan2
- CHMP7 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV57533001; called by muse, mutect2, varscan2
- CHN1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs376827050; called by muse, mutect2, varscan2
- CHRM3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 102/338 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55084430; called by muse, mutect2, varscan2
- CLCA2 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 107/217 reads (49%) | catalogued as COSV65288707; called by muse, mutect2, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, mutect2, varscan2
- CLDN16 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.187); catalogued as COSV53228493; called by muse, mutect2, varscan2
- CLDN3 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV67777415; called by muse, mutect2, varscan2
- CLEC17A | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV60429672; called by muse, mutect2, varscan2
- CLEC4E | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55227356; called by muse, mutect2, varscan2
- CLEC4E | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55227370; called by muse, mutect2
- CLEC4M | c.785-1G>A p.X262_splice | Splice Site (SNP) | VAF 39/176 reads (22%) | catalogued as COSV50224183; called by muse, mutect2, varscan2
- CLIC5 | c.1226G>A p.R409Q (on ENST00000185206 / NM_001370649.1; = p.R250Q on NM_016929.5) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs193274454, COSV51765406; called by muse, mutect2, varscan2
- CLSTN2 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV71724989; called by muse, mutect2, varscan2
- CLSTN3 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV56940223; called by muse, mutect2, varscan2
- CLUL1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV58113461; called by muse, mutect2, varscan2
- CLVS1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV57972916; called by muse, mutect2, varscan2
- CLYBL | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 45/78 reads (58%) | catalogued as rs752468741, COSV59217650; called by muse, mutect2, varscan2
- CMBL | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs752322916, COSV56985293; called by muse, mutect2, varscan2
- CMYA5 | c.11210C>T p.S3737L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV71409401, COSV71410368; called by muse, mutect2, varscan2
- CNGA4 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs567320946, COSV66007059; called by muse, mutect2, varscan2
- CNGB3 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60684144, COSV60689104; called by muse, mutect2, varscan2
- CNNM4 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 187/616 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.498); catalogued as COSV65660890, COSV65662101; called by muse, mutect2, varscan2
- CNOT1 | c.6938T>C p.I2313T | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54701492; called by muse, mutect2, varscan2
- CNOT2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV57506870; called by muse, mutect2, varscan2
- CNTN2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs771113073, COSV59352866; called by muse, mutect2, varscan2
- CNTN4 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61880682, COSV61880908; called by muse, mutect2, varscan2
- CNTN4 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.195); catalogued as COSV61878503; called by muse, mutect2
- CNTN4 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.176); catalogued as COSV61867360; called by muse, mutect2, varscan2
- CNTN5 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54355238; called by muse, mutect2
- CNTNAP4 | c.3868A>T p.K1290* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56699711; called by muse, mutect2, varscan2
- COA7 | c.368T>G p.V123G | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.171); catalogued as COSV65299970; called by muse, mutect2, varscan2
- COBL | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as COSV54358148; called by muse, mutect2, varscan2
- COBLL1 | c.2902C>T p.P968S (on ENST00000392717; = p.P930S on NM_014900.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV52076196; called by muse, mutect2, varscan2
- COL10A1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54574650; called by muse, mutect2, varscan2
- COL18A1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62707132; called by muse, mutect2, varscan2
- COL18A1 | c.2729C>T p.P910L (on ENST00000359759 / NM_130444.3; = p.P675L on NM_030582.4) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs751547351, COSV62707144; called by muse, mutect2, varscan2
- COL18A1 | c.3802A>T p.T1268S (on ENST00000359759 / NM_130444.3; = p.T1033S on NM_030582.4) | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.052); catalogued as COSV100645408; called by muse, mutect2, varscan2
- COL18A1 | c.3803C>T p.T1268I (on ENST00000359759 / NM_130444.3; = p.T1033I on NM_030582.4) | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1422527614, COSV100645409; called by muse, mutect2, varscan2
- COL20A1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368044718; called by muse, mutect2, varscan2
- COL21A1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as rs867948640, COSV55159384; called by muse, mutect2, varscan2
- COL24A1 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV65313893; called by muse, mutect2, varscan2
- COL24A1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV65313898; called by muse, mutect2
- COL27A1 | c.4703G>A p.G1568E | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61930683; called by muse, mutect2, varscan2
- COL28A1 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV68084581; called by muse, mutect2, varscan2
- COL4A2 | c.3124C>G p.P1042A | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV64628474, COSV64633989; called by muse, mutect2, varscan2
- COL4A3 | c.2819G>A p.G940E | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257562; called by muse, mutect2, varscan2
- COL4A4 | c.4408C>T p.L1470F | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); catalogued as COSV61636461; called by muse, mutect2, varscan2
- COL4A4 | c.3983G>A p.G1328E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV61634691, COSV61636464; called by muse, mutect2
- COL4A4 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61636471; called by muse, mutect2, varscan2
- COL5A2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV66415087; called by muse, mutect2, varscan2
- COL5A3 | c.3827C>T p.S1276L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53418814; called by muse, mutect2, varscan2
- COL5A3 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1313783131, COSV53418826; called by muse, mutect2, varscan2
- COL5A3 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53414766; called by muse, mutect2
- COL5A3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99319514; called by muse, mutect2
- COL6A2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs150057026; ClinVar: uncertain significance; called by muse, varscan2
- COL6A2 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs368878639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs777759049, COSV55081337; called by muse, varscan2
- COL6A5 | c.6166G>A p.A2056T (on ENST00000312481; = p.A2052T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV55215922; called by muse, mutect2, varscan2
- COL6A6 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV62037037; called by muse, mutect2, varscan2
- COL7A1 | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 156/363 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.863); catalogued as CM074763, COSV60393146; called by muse, mutect2, varscan2
- COL8A2 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57443421; called by muse, mutect2, varscan2
- COL9A3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV58987167; called by muse, mutect2, varscan2
- COLQ | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV101082450, COSV67526017; called by muse, mutect2, varscan2
- COQ8A | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64659266; called by muse, mutect2, varscan2
- COX8C | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379681773, COSV56409695; called by muse, mutect2, varscan2
- CPA3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs145828911, COSV56044334, COSV56047504; called by muse, mutect2, varscan2
- CPLANE1 | c.8990C>T p.S2997F | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57073852; called by muse, mutect2, varscan2
- CPLX3 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1223432641, COSV59003694; called by muse, mutect2, varscan2
- CR1 | c.4028G>A p.G1343E | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65457866; called by muse, varscan2
- CR1 | c.4132G>A p.G1378R | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367555644, COSV65463092; called by muse, varscan2
- CRACR2A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52918263; called by muse, mutect2, varscan2
- CRB1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs1230478193, COSV100957897, COSV66329881; called by muse, mutect2, varscan2
- CRB2 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV63505468; called by muse, mutect2, varscan2
- CRISP2 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59256799; called by muse, mutect2, varscan2
- CRLF1 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV62261003; called by muse, mutect2, varscan2
- CRYBB2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs866268820, COSV68005292; called by muse, mutect2, varscan2
- CRYBG3 | c.8101G>A p.V2701I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV51716057; called by muse, mutect2, varscan2
- CSE1L | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773304297, COSV53705084; called by muse, mutect2, varscan2
- CSF1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs1045404870, COSV60035345; called by muse, mutect2, varscan2
- CSF1R | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as rs777239066, COSV53842868; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs749633565, COSV65676401; called by muse, mutect2, varscan2
- CSMD1 | c.5389C>T p.P1797S (on ENST00000520002; = p.P1796S on NM_033225.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1260339604, COSV59381426; called by muse, mutect2
- CSMD1 | c.2981C>T p.S994F (on ENST00000520002; = p.S993F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV59381439; called by muse, mutect2, varscan2
- CSMD2 | c.6137C>T p.S2046F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as rs140911773; called by muse, mutect2, varscan2
- CSMD2 | c.5505+1G>A p.X1835_splice | Splice Site (SNP) | VAF 58/210 reads (28%) | catalogued as COSV53960744; called by muse, mutect2, varscan2
- CSMD3 | c.1661G>A p.G554E (on ENST00000297405 / NM_001363185.1; = p.G450E on NM_052900.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs1361326399, COSV52183814; called by muse, mutect2, varscan2
- CSRNP3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV58785546; called by muse, mutect2, varscan2
- CTAGE15 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV101372163; called by muse, mutect2, varscan2
- CTAGE15 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV101372164; called by mutect2, varscan2
- CTNND2 | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV58926772; called by muse, mutect2, varscan2
- CTNND2 | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58926780; called by muse, mutect2, varscan2
- CTR9 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs369118804, COSV63729630; called by muse, mutect2, varscan2
- CTSS | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64567057; called by muse, mutect2, varscan2
- CTTNBP2NL | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 89/162 reads (55%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.776); catalogued as COSV54746860; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 154/971 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV54746869; called by muse, mutect2, varscan2
- CTXN3 | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV101060698; called by muse, mutect2, varscan2
- CXCL13 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.736); catalogued as COSV54493622; called by muse, mutect2, varscan2
- CYP11B1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1187657301, COSV52830210; called by muse, mutect2, varscan2
- CYP2C9 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53252757; called by muse, mutect2, varscan2
- CYP3A4 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.117); catalogued as COSV60504167; called by muse, mutect2
- CYP3A43 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs767486696, COSV55937969; called by muse, mutect2, varscan2
- CYP4F11 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 130/707 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs267605328, COSV56129469; called by muse, mutect2, varscan2
- CYP4F11 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 77/488 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs765657481, COSV56128224, COSV56129477; called by muse, mutect2, varscan2
- CYP4F2 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 94/581 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55621483; called by muse, mutect2, varscan2
- CYP4X1 | c.1209G>A p.G403= | Splice Region (SNP) | VAF 92/311 reads (30%) | catalogued as COSV64150780; called by muse, mutect2, varscan2
- CYTIP | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1293184738, COSV51636068; called by muse, mutect2, varscan2
- CYTIP | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV51633316; called by muse, mutect2, varscan2
- CYTIP | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs761105943, COSV99938867; called by muse, mutect2, varscan2
- DAAM1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150648068; called by muse, mutect2, varscan2
- DAB1 | c.1142C>T p.P381L (on ENST00000371231; = p.P348L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV64697916; called by muse, mutect2, varscan2
- DAB1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59725348; called by muse, mutect2, varscan2
- DBH | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV55041703; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 86/435 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DCAF4L2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV60478217, COSV60481290; called by muse, varscan2
- DCAF4L2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60476386, COSV60476821; called by muse, mutect2, varscan2
- DCDC2 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65833933; called by muse, mutect2, varscan2
- DCLK3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1559391017, COSV69364680; called by muse, mutect2, varscan2
- DCLK3 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 217/466 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1403156196, COSV69364683; called by muse, mutect2, varscan2
- DCP1B | c.651G>A p.Q217= | Splice Region (SNP) | VAF 97/324 reads (30%) | catalogued as COSV54972351; called by muse, mutect2, varscan2
- DCX | c.1045G>A p.D349N (on ENST00000636035 / NM_001195553.2; = p.D343N on NM_000555.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.956); catalogued as CD010105, COSV57575215; called by muse, mutect2, varscan2
- DDR1 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.091); catalogued as COSV100241589; called by muse, varscan2
- DDR1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs199740590, COSV100241592, COSV61319586; called by muse, varscan2
- DDX27 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267605978, COSV65610710; called by muse, mutect2, varscan2
- DDX60 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67099276; called by muse, mutect2, varscan2
- DENND1A | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 55/195 reads (28%) | catalogued as COSV65332392; called by muse, mutect2, varscan2
- DENND3 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 75/345 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52806734; called by muse, mutect2, varscan2
- DENND5B | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV60903519; called by mutect2, varscan2
- DGAT2L6 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs768688431, COSV60718716; called by muse, mutect2, varscan2
- DGKB | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV51807484; called by muse, mutect2, varscan2
- DGKI | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55974880; called by muse, mutect2, varscan2
- DGKK | c.1811G>T p.R604I | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV65709377; called by muse, varscan2
- DGKQ | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs750412054, COSV56619613; called by muse, mutect2, varscan2
- DHCR7 | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62796678; called by muse, mutect2, varscan2
- DHX37 | c.2347del p.R783Afs*8 | Frame Shift Del (DEL) | VAF 53/272 reads (19%) | catalogued as COSV100439422; called by mutect2, pindel, varscan2
- DHX40 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as rs769501766, COSV52069953; called by muse, mutect2, varscan2
- DIDO1 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs943598507, COSV56625478; called by muse, mutect2, varscan2
- DIP2A | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV100596227; called by muse, mutect2, varscan2
- DIXDC1 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59463545; called by muse, mutect2, varscan2
- DLG2 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV54683855; called by muse, mutect2, varscan2
- DLGAP4 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as COSV59423252; called by muse, mutect2, varscan2
- DMBT1 | c.3055G>A p.D1019N (on ENST00000338354 / NM_001377530.1; = p.D520N on NM_004406.3) | Missense Mutation (SNP) | VAF 255/641 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs773492969, COSV57545842; called by muse, mutect2, varscan2
- DMBT1 | c.5555G>A p.G1852D (on ENST00000338354 / NM_001377530.1; = p.G1095D on NM_004406.3) | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV57561185; called by muse, mutect2, varscan2
- DMBX1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV63602596; called by muse, mutect2, varscan2
- DMD | c.10997C>T p.S3666F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58952121, COSV58957432; called by muse, mutect2, varscan2
- DMP1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1363177923, COSV56822094; called by muse, mutect2, varscan2
- DMXL2 | c.8963C>T p.S2988F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51843147; called by muse, mutect2, varscan2
- DNAH10 | c.2905C>T p.H969Y (on ENST00000409039; = p.H908Y on NM_207437.3) | Missense Mutation (SNP) | VAF 202/658 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV69001269; called by muse, mutect2, varscan2
- DNAH11 | c.2695C>T p.P899S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV60947872; called by mutect2, varscan2
- DNAH11 | c.7798G>A p.D2600N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60980659; called by muse, mutect2
- DNAH11 | c.9680C>T p.A3227V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV60980669; called by muse, mutect2, varscan2
- DNAH11 | c.10037G>A p.R3346Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs761713335, COSV60941356; called by muse, mutect2, varscan2
- DNAH14 | c.685G>A p.E229K (on ENST00000445597; = p.E52K on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs777899875, COSV64782571; called by muse, mutect2, varscan2
- DNAH3 | c.5043G>A p.M1681I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV54533151; called by muse, mutect2, varscan2
- DNAH5 | c.13763A>G p.K4588R | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.699); catalogued as COSV54251009; called by muse, mutect2, varscan2
- DNAH5 | c.11938G>A p.E3980K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs1221618846, COSV54241325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.10312C>T p.L3438F | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1165709485, COSV54251029; called by muse, mutect2, varscan2
- DNAH5 | c.8821-1G>A p.X2941_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as rs1060501454, COSV54242372; called by muse, mutect2, varscan2
- DNAH5 | c.8020G>A p.E2674K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868830185, COSV54238491; called by muse, mutect2, varscan2
- DNAH5 | c.6854C>T p.P2285L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV54251051; called by muse, mutect2, varscan2
- DNAH5 | c.6274G>A p.E2092K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs865876907, COSV54246857; called by muse, mutect2, varscan2
- DNAH5 | c.2256G>A p.M752I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV54251077; called by muse, mutect2, varscan2
- DNAH5 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.074); catalogued as rs141072655; called by muse, mutect2, varscan2
- DNAH5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs866784113, COSV54205135; called by muse, mutect2, varscan2
- DNAH7 | c.10445G>A p.G3482E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56785294; called by muse, mutect2, varscan2
- DNAH7 | c.5650C>T p.R1884* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as rs201461887; called by muse, mutect2, varscan2
- DNAH7 | c.5368G>A p.V1790I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV56785329; called by muse, mutect2, varscan2
- DNAH8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV59479418; called by muse, mutect2, varscan2
- DNAH8 | c.5937C>T p.I1979= | Splice Region (SNP) | VAF 16/69 reads (23%) | catalogued as COSV59479437; called by muse, mutect2, varscan2
- DNAH8 | c.8071G>A p.E2691K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201862791, COSV59479455; called by muse, mutect2, varscan2
- DNAH8 | c.11982G>A p.W3994* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV59479471; called by muse, mutect2, varscan2
- DNAH8 | c.12965G>A p.W4322* | Nonsense Mutation (SNP) | VAF 74/217 reads (34%) | catalogued as COSV59479480; called by muse, mutect2, varscan2
- DNAJC13 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53445460; called by muse, mutect2, varscan2
- DNAJC21 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs374025634; called by muse, mutect2, varscan2
- DNAJC21 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1386295980, COSV57762614; called by muse, mutect2, varscan2
- DNTTIP1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV65459511; called by muse, mutect2, varscan2
- DOCK3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56549182; called by muse, varscan2
- DOCK3 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV56531929; called by muse, varscan2
- DOCK7 | c.2546T>C p.I849T | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV52020849; called by muse, mutect2, varscan2
- DPH6 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV56619537; called by muse, mutect2, varscan2
- DPM2 | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55948874; called by muse, mutect2, varscan2
- DPP10 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59686682; called by muse, mutect2, varscan2
- DPP10 | c.1603A>T p.I535F | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59726375; called by muse, mutect2, varscan2
- DPP10 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59707026; called by muse, mutect2, varscan2
- DPPA2 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 146/339 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs368412698; called by muse, mutect2, varscan2
- DPRX | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as rs775233324, COSV64949965; called by muse, mutect2, varscan2
- DPYD | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1416074059, COSV64614138; called by muse, mutect2, varscan2
- DPYD | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV64614144; called by muse, mutect2, varscan2
- DROSHA | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs369352228; called by muse, mutect2, varscan2
- DSCAM | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 86/409 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs369222297, COSV68036796; called by muse, mutect2, varscan2
- DSCAM | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV68026863; called by muse, mutect2, varscan2
- DSG4 | c.425A>G p.E142G | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV57397435; called by muse, mutect2, varscan2
- DSG4 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs746856669, COSV57393950; called by muse, mutect2, varscan2
- DSP | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs773113261, COSV65795864; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.4735C>T p.R1579W | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755868373, COSV65793824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.7790C>T p.S2597F | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV65793967; called by muse, mutect2, varscan2
- DSTYK | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV65688420; called by muse, mutect2, varscan2
- DTX3 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 56/228 reads (25%) | catalogued as COSV54090461; called by muse, mutect2, varscan2
- DUOX1 | c.2645C>T p.S882F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58486409; called by muse, mutect2, varscan2
- EDARADD | c.76G>A p.E26K (on ENST00000334232 / NM_145861.4; = p.E16K on NM_080738.4) | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62065063; called by muse, mutect2, varscan2
- EIF3B | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 177/573 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs768314023, COSV62802597, COSV62804870; called by muse, mutect2, varscan2
- EIF3I | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59085713; called by muse, mutect2, varscan2
- EIF4G3 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV51693788; called by muse, mutect2, varscan2
- ELAVL4 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV63913881, COSV63915014; called by muse, mutect2, varscan2
- ELN | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52715391; called by muse, mutect2, varscan2
- ELP6 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV56133170; called by muse, mutect2, varscan2
- EMB | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs766190226, COSV57484438; called by muse, mutect2, varscan2
- EMCN | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV56464229; called by muse, mutect2, varscan2
- EMILIN2 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54427444; called by muse, mutect2, varscan2
- ENAM | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV68536990; called by muse, mutect2, varscan2
- ENAM | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs371648352; called by muse, mutect2, varscan2
- ENO2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.159); catalogued as COSV57545743; called by muse, mutect2, varscan2
- ENOX2 | c.343C>T p.L115F (on ENST00000338144 / NM_001382520.1; = p.L86F on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100584542, COSV57657933; called by muse, mutect2, varscan2
- ENPEP | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV54457266; called by muse, mutect2, varscan2
- ENPP6 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV57066728, COSV57072151; called by muse, mutect2, varscan2
- ENTPD1 | c.1360T>C p.Y454H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64604283; called by muse, mutect2, varscan2
- EP400 | c.3719C>T p.S1240F | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57768722; called by muse, mutect2, varscan2
- EPC2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773161874, COSV51549362; called by muse, mutect2, varscan2
- EPHA3 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866025221, COSV60719513, COSV60726782; called by muse, mutect2, varscan2
- EPHA7 | c.2460G>A p.W820* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV65191522; called by muse, mutect2, varscan2
- EPHA8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV51298114; called by muse, mutect2, varscan2
- EPHB1 | c.2214G>A p.M738I | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV67660012; called by muse, mutect2, varscan2
- EPHB2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as rs763188025, COSV65861269; called by muse, mutect2, varscan2
- EPPK1 | c.6082G>A p.E2028K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV73262363; called by muse, mutect2, varscan2
- ERAL1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 75/303 reads (25%) | catalogued as rs751263775, COSV54740967; called by muse, mutect2, varscan2
- ERBB4 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV53501228; called by muse, mutect2, varscan2
- ERC2 | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.92); catalogued as COSV55662570; called by muse, mutect2, varscan2
- ERH | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV53681115; called by muse, mutect2, varscan2
- ERMN | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs554539666, COSV68075808; called by muse, mutect2, varscan2
- ERO1A | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV67471186; called by muse, mutect2, varscan2
- ESR1 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV52802368; called by muse, mutect2, varscan2
- ESRP2 | c.973C>T p.R325C (on ENST00000565858 / NM_001365264.1; = p.R315C on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757516890, COSV52176121; called by muse, mutect2, varscan2
- ETNK1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56889721; called by muse, varscan2
- ETNK1 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56889731; called by muse, varscan2
- EVPL | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs373479315; called by muse, mutect2, varscan2
- EXOC4 | c.37A>C p.T13P | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV54122181; called by muse, varscan2
- EXOC4 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV54122220; called by muse, mutect2, varscan2
- EXOSC7 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312053486, COSV55557174; called by muse, mutect2, varscan2
- EXPH5 | c.4325G>A p.R1442K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV56208045; called by muse, mutect2, varscan2
- EYA1 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV58173797; called by muse, mutect2
- EYA1 | c.1564C>G p.P522A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100379301, COSV58173817; called by muse, mutect2, varscan2
- EYA4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV62046987, COSV62056033; called by muse, mutect2, varscan2
- F10 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 137/208 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM121359, COSV65023123; called by muse, mutect2, varscan2
- F13B | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66374860; called by muse, mutect2, varscan2
- F5 | c.6643C>T p.R2215C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs984836970, COSV63121098; called by muse, mutect2, varscan2
- F5 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63128223; called by muse, mutect2, varscan2
- F8 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 89/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM062668, CM070104, CM145558, COSV64273953; called by muse, mutect2, varscan2
- FAM126B | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53775164; called by muse, mutect2, varscan2
- FAM155A | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs774707777, COSV65586826; called by muse, mutect2, varscan2
- FAM168B | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV66304795; called by muse, mutect2, varscan2
- FAM171A1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV65320028; called by muse, mutect2, varscan2
- FAM181A | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV50891428; called by muse, mutect2, varscan2
- FAM181A | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1317736954, COSV50891448, COSV99967928; called by muse, mutect2, varscan2
- FAM214A | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV55927181; called by muse, mutect2, varscan2
- FAM216A | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.237); catalogued as COSV62195503; called by muse, mutect2, varscan2
- FAM228A | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV54596373; called by muse, mutect2, varscan2
- FAM3D | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 62/321 reads (19%) | catalogued as COSV62559550; called by muse, mutect2, varscan2
- FAM47A | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as rs1555968153, COSV60496368, COSV60499742; called by muse, mutect2, varscan2
- FAM47A | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867182777, COSV60497794; called by muse, mutect2, varscan2
- FAM47B | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.844); catalogued as rs764311139, COSV61455548; called by muse, mutect2, varscan2
- FAM47B | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV61454002; called by muse, mutect2, varscan2
- FAM83E | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV52377263; called by muse, mutect2, varscan2
- FAN1 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs748042109, COSV62951485; called by muse, mutect2, varscan2
- FANCD2OS | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1280710958, COSV55034252; called by muse, mutect2, varscan2
- FANCI | c.3113C>T p.S1038L (on ENST00000310775 / NM_001376911.1; = p.S978L on NM_018193.3) | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55534647; called by muse, mutect2, varscan2
- FANK1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 134/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64157165; called by muse, mutect2, varscan2
- FASLG | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1301499867, COSV60680440; called by muse, mutect2, varscan2
- FASN | c.4280C>T p.S1427F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV60760904; called by muse, mutect2, varscan2
- FASTK | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV52542236; called by muse, mutect2, varscan2
- FAT3 | c.6637C>T p.P2213S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99969252; called by muse, mutect2, varscan2
- FAT3 | c.6638C>T p.P2213L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99969253; called by muse, mutect2, varscan2
- FBLIM1 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV60028331; called by muse, mutect2, varscan2
- FBN2 | c.7657G>A p.G2553R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52544552; called by muse, mutect2, varscan2
- FBXO21 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100401832; called by muse, mutect2, varscan2
- FBXO24 | c.899A>G p.H300R (on ENST00000241071 / NM_033506.3; = p.H338R on NM_012172.5) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV53828058; called by muse, mutect2, varscan2
- FBXO9 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV55057193; called by muse, mutect2, varscan2
- FBXW12 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56485485; called by muse, mutect2, varscan2
- FBXW9 | c.682C>G p.R228G (on ENST00000587955; = p.R238G on NM_032301.3) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as rs770468401, COSV66710499; called by muse, mutect2, varscan2
- FCRL2 | c.1274T>A p.I425K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV63835074; called by muse, mutect2, varscan2
- FCRL2 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); catalogued as COSV63835084; called by muse, mutect2, varscan2
- FCRLA | c.457A>G p.I153V (on ENST00000367959; = p.I130V on NM_032738.4) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV52688364; called by muse, mutect2, varscan2
- FDXR | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs766174200, COSV99502351; called by muse, mutect2, varscan2
- FER1L6 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV67552761; called by muse, mutect2, varscan2
- FERMT1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1056137, COSV54097247; called by muse, mutect2, varscan2
- FERMT3 | c.361T>G p.F121V | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV54183638; called by muse, mutect2, varscan2
- FGA | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57400687; called by muse, mutect2, varscan2
- FGB | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV57419509; called by muse, mutect2, varscan2
- FGD2 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780569281, COSV51466074; called by muse, mutect2, varscan2
- FGF17 | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 44/103 reads (43%) | catalogued as rs1441950100, COSV63925853; called by muse, mutect2, varscan2
- FGF6 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57404128; called by muse, varscan2
- FGFR2 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60639450; called by muse, mutect2, varscan2
- FGFR3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs778645659, COSV53403407; called by muse, mutect2, varscan2
- FHOD3 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs750087235, COSV57188371; called by muse, mutect2, varscan2
- FILIP1 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99385802; called by muse, mutect2, varscan2
- FLG | c.3614A>T p.D1205V | Missense Mutation (SNP) | VAF 309/890 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV64248859; called by muse, mutect2, varscan2
- FLG2 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV66170591, COSV66173164; called by muse, mutect2, varscan2
- FLI1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55647749; called by muse, mutect2, varscan2
- FLNA | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61051388; called by muse, mutect2, varscan2
- FLNB | c.7253C>T p.S2418F | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV55892659; called by muse, mutect2, varscan2
- FLNC | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as rs201006462; called by muse, mutect2, varscan2
- FMN2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60452910; called by muse, mutect2, varscan2
- FMO1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61447799; called by muse, varscan2
- FMO1 | c.1257-1G>A p.X419_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV61447805; called by muse, mutect2, varscan2
- FMO2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52947798, COSV52950357; called by muse, mutect2, varscan2
- FOLH1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57051921, COSV99923753; called by muse, mutect2, varscan2
- FOXN1 | c.1653T>G p.D551E | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV56884147; called by muse, mutect2, varscan2
- FREM1 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746156557, COSV66526811; called by mutect2, varscan2
- FRK | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs762257926, COSV101606678; called by muse, mutect2, varscan2
- FRMPD1 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66700481; called by muse, mutect2, varscan2
- FRYL | c.1944G>A p.W648* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51962027; called by muse, mutect2, varscan2
- FRYL | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51950872; called by muse, mutect2, varscan2
- FYB1 | c.2275C>T p.L759F (on ENST00000351578 / NM_199335.5; = p.L805F on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs867070342, COSV60940756, COSV60956085; called by mutect2, varscan2
- FYB2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs868676186, COSV58582820, COSV58583406; called by muse, mutect2, varscan2
- G3BP1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs896356394, COSV62365718; called by muse, mutect2, varscan2
- GAB4 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV68755213; called by muse, mutect2, varscan2
- GABRA3 | c.821A>T p.K274I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64805170; called by muse, mutect2, varscan2
- GABRB2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50904046; called by muse, mutect2, varscan2
- GABRE | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100944205, COSV64819519; called by muse, mutect2, varscan2
- GAK | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100033967; called by muse, mutect2, varscan2
- GAK | c.3167-1G>A p.X1056_splice | Splice Site (SNP) | VAF 21/138 reads (15%) | catalogued as COSV100033968, COSV99041255; called by muse, mutect2, varscan2
- GALC | c.615T>A p.Y205* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV54330127; called by muse, mutect2, varscan2
- GALNT14 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1558439398, COSV61107469; called by muse, mutect2, varscan2
- GAS2 | c.147G>A p.G49= | Splice Region (SNP) | VAF 16/91 reads (18%) | catalogued as COSV53409722; called by muse, mutect2, varscan2
- GATAD2B | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV100897771, COSV64086008; called by muse, mutect2, varscan2
- GBP2 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs778334754, COSV65070417; called by muse, mutect2, varscan2
- GCM1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs375109372; called by muse, mutect2, varscan2
- GDF6 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV54623475, COSV54627738; called by muse, mutect2, varscan2
- GDI2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV66336112; called by muse, mutect2, varscan2
- GEMIN5 | c.4082C>T p.S1361L | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53564700; called by muse, mutect2, varscan2
- GFRA2 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV60781826; called by muse, mutect2
- GHSR | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as COSV53841545; called by muse, mutect2, varscan2
- GHSR | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV53841557; called by muse, mutect2, varscan2
- GIMAP6 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV100188062, COSV61033781; called by muse, mutect2, varscan2
- GIPC3 | c.591C>T p.F197= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as rs759536524, COSV59260296; called by muse, mutect2, varscan2
- GK2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1417995112, COSV62626181; called by muse, mutect2, varscan2
- GLCE | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55948394; called by muse, mutect2, varscan2
- GLDC | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58685031; called by muse, mutect2, varscan2
- GLG1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs760881916, COSV52674275; called by muse, mutect2, varscan2
- GLI2 | c.2501C>T p.S834F (on ENST00000361492 / NM_001374353.1; = p.S851F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs762343399, COSV58051185; called by muse, mutect2, varscan2
- GLI2 | c.4701G>A p.M1567I (on ENST00000361492 / NM_001374353.1; = p.M1584I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.378); catalogued as COSV58051189; called by muse, mutect2, varscan2
- GLIPR1L2 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57556187; called by muse, mutect2, varscan2
- GLYATL1 | c.449G>A p.G150E (on ENST00000317391 / NM_001354699.1; = p.G181E on NM_080661.4) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.445); catalogued as rs199854361, COSV55611409; called by muse, mutect2, varscan2
- GMIP | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99179500; called by muse, mutect2, varscan2
- GNA15 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 112/390 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs868247802, COSV53588161; called by muse, mutect2, varscan2
- GOLGA3 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 198/997 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52643011; called by muse, mutect2, varscan2
- GOSR1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1321800002, COSV56720950; called by muse, mutect2, varscan2
- GOT1L1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV56875107; called by muse, mutect2, varscan2
- GPC3 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs750171653, COSV63671793; called by muse, mutect2, varscan2
- GPC5 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as rs1456569867, COSV65580528, COSV65629055; called by muse, mutect2, varscan2
- GPHN | c.2108T>A p.M703K (on ENST00000315266 / NM_001377519.1; = p.M736K on NM_020806.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV59492999; called by muse, mutect2, varscan2
- GPM6B | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV57424491; called by muse, mutect2, varscan2
- GPR171 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56390657; called by muse, mutect2, varscan2
- GPRIN2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV65400378; called by muse, varscan2
- GRAP2 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866441319, COSV59997098; called by muse, mutect2, varscan2
- GREM2 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.135); catalogued as COSV58957130; called by muse, mutect2, varscan2
- GRID1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs1291746299, COSV60052320; called by muse, mutect2, varscan2
- GRIN2A | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as COSV58052167; called by muse, mutect2, varscan2
- GRIP1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1015140694, COSV54042263; called by muse, mutect2, varscan2
- GRK1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV59554215; called by muse, mutect2, varscan2
- GRK4 | c.323G>A p.R108K (on ENST00000398052 / NM_182982.3; = p.R76K on NM_005307.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61670598; called by muse, mutect2, varscan2
- GRM6 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489911945, COSV99179805; called by muse, mutect2, varscan2
- GRXCR2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs447402, COSV65060697; called by muse, mutect2, varscan2
- GSDMB | c.716C>T p.S239L (on ENST00000418519 / NM_001165958.1; = p.S226L on NM_001042471.1) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV58782577; called by muse, mutect2, varscan2
- GUCA1A | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV50005348; called by muse, mutect2, varscan2
- GUCY1A1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV56651434, COSV56656396; called by muse, mutect2, varscan2
- GUCY2C | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53795361; called by muse, mutect2, varscan2
- GUCY2C | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as rs775449520, COSV53790074, COSV53790453; called by muse, mutect2, varscan2
- GUK1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs368698841, COSV57157038; called by muse, mutect2, varscan2
- H2AC1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs1418751341, COSV51237093, COSV99219604; called by muse, mutect2, varscan2
- H3-5 | c.402A>T p.R134S | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61188237; called by muse, mutect2, varscan2
- HABP2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV63637946; called by muse, mutect2, varscan2
- HAL | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as rs760789510, COSV54120306; called by muse, mutect2, varscan2
- HAUS4 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV52828251; called by muse, mutect2, varscan2
- HAUS6 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs868190886, COSV65840843; called by muse, mutect2, varscan2
- HAX1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV55167516, COSV99671945; called by muse, mutect2, varscan2
- HBB | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as CD800003, CX075729, COSV58943181; called by muse, mutect2, varscan2
- HCN1 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs775806199, COSV57498097; called by muse, mutect2, varscan2
- HCN1 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.823); catalogued as rs767837343, COSV57536521; called by muse, mutect2, varscan2
- HCN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV57536526; called by muse, mutect2, varscan2
- HDC | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs867414908, COSV51081078; called by muse, mutect2, varscan2
- HDGFL3 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.117); catalogued as COSV55208649; called by muse, mutect2, varscan2
- HECTD1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV67949070; called by muse, mutect2, varscan2
- HECW2 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs750652650, COSV53666245, COSV53673949; called by muse, mutect2, varscan2
- HEG1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV60761579; called by muse, mutect2, varscan2
- HEMK1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs373334073; called by muse, varscan2
- HEPH | c.131G>A p.R44K (on ENST00000343002; = p.R98K on NM_138737.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57961481; called by muse, mutect2, varscan2
- HEPHL1 | c.1925G>A p.R642K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59896332; called by muse, mutect2, varscan2
- HERC1 | c.9034C>G p.R3012G | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV71247403, COSV71250208; called by muse, mutect2, varscan2
- HERC2 | c.6728C>T p.T2243I | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); catalogued as COSV55322301; called by muse, mutect2, varscan2
- HERC5 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.344); catalogued as COSV52044847; called by muse, mutect2, varscan2
- HGF | c.2145G>A p.W715* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV55956630; called by muse, mutect2, varscan2
- HGF | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55947160; called by muse, mutect2, varscan2
- HGSNAT | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369292480; called by muse, mutect2
- HHIPL2 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 101/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58567767; called by muse, mutect2, varscan2
- HIPK2 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV69212047; called by muse, mutect2, varscan2
- HIRA | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54279655; called by muse, mutect2, varscan2
- HJV | c.1243C>T p.L415F (on ENST00000336751 / NM_213653.4; = p.L302F on NM_145277.5) | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60953160; called by muse, mutect2, varscan2
- HLA-B | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.745); catalogued as COSV101317736, COSV69523034; called by muse, mutect2, varscan2
- HOMER2 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58488586; called by muse, mutect2, varscan2
- HOOK1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV64620909; called by muse, mutect2, varscan2
- HORMAD2 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031754088, COSV60900832; called by muse, mutect2, varscan2
- HOXD1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58924464; called by muse, mutect2
- HPSE | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100264517, COSV60988752; called by muse, mutect2, varscan2
- HR | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57194663; called by muse, mutect2, varscan2
- HRH1 | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 143/347 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as COSV101229095; called by muse, mutect2, varscan2
- HSD11B1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV54828826; called by muse, mutect2, varscan2
- HSDL2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52714594, COSV52717241; called by muse, mutect2, varscan2
- HSPA1L | c.645T>A p.D215E | Missense Mutation (SNP) | VAF 261/796 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.26); catalogued as COSV65149485; called by muse, mutect2, varscan2
- HTR3D | c.784C>T p.P262S (on ENST00000382489 / NM_001163646.2; = p.P89S on NM_182537.3) | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV61915526; called by muse, varscan2
- HTR3D | c.815G>A p.S272N (on ENST00000382489 / NM_001163646.2; = p.S99N on NM_182537.3) | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV61915537; called by muse, varscan2
- HTT | c.9116C>T p.S3039F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61869032; called by muse, mutect2, varscan2
- HUWE1 | c.11522C>T p.P3841L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1556916775, COSV53363533; called by muse, mutect2, varscan2
- HYAL4 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1267029898, COSV56140399; called by muse, mutect2, varscan2
- HYDIN | c.13381C>T p.P4461S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV66638072; called by muse, mutect2, varscan2
- HYDIN | c.3765G>A p.M1255I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV66831088; called by muse, varscan2
- HYDIN | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV99864598; called by mutect2, varscan2
- IARS1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117236; called by muse, mutect2, varscan2
- ICE1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs747306242, COSV56825259; called by muse, mutect2, varscan2
- ICE1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV56825305; called by muse, varscan2
- ICE1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56832184; called by muse, varscan2
- ICE1 | c.4892C>T p.P1631L | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56832200; called by muse, mutect2, varscan2
- IFIH1 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55130119; called by muse, mutect2, varscan2
- IFNA7 | c.530T>C p.F177S | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53332297; called by muse, mutect2, varscan2
- IFNAR2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 157/578 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1485446524, COSV51618016, COSV99270047; called by muse, mutect2, varscan2
- IFNB1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV101207777, COSV66525692; called by muse, mutect2, varscan2
- IGFALS | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51908434; called by muse, mutect2, varscan2
- IGFN1 | c.2147C>T p.T716I (on ENST00000295591 / NM_001367841.1; = p.T3173I on NM_001164586.2) | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV55184292; called by muse, mutect2, varscan2
- IGHG3 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 119/430 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1189696934; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.784); catalogued as rs373204588; called by muse, varscan2
- IGLV2-14 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 130/579 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs763905502; called by muse, mutect2, varscan2
- IGSF1 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs866536788, COSV63840237; called by muse, mutect2, varscan2
- IGSF1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as COSV63837621; called by muse, mutect2, varscan2
- IGSF10 | c.4358G>A p.R1453K | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56791476; called by muse, mutect2, varscan2
- IGSF9 | c.2464G>A p.D822N (on ENST00000368094 / NM_001135050.2; = p.D806N on NM_020789.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs958443722, COSV57423607; called by muse, mutect2, varscan2
- IGSF9B | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); catalogued as COSV58072670; called by muse, mutect2, varscan2
- IKZF4 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV56271534; called by muse, mutect2, varscan2
- IL12RB1 | c.1876G>A p.G626S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV74045435, COSV74045672; called by muse, mutect2, varscan2
- IL23R | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs769559634, COSV61376260; called by muse, mutect2, varscan2
- IL31RA | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV61692543; called by muse, mutect2, varscan2
- IL4R | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50170601; called by muse, mutect2, varscan2
- IL7R | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57405848, COSV57407051, COSV57413960; called by muse, mutect2, varscan2
- IMPACT | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs141355151; called by muse, mutect2, varscan2
- IMPG2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV51985532; called by muse, mutect2, varscan2
- IMPG2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV51985541; called by muse, mutect2, varscan2
- ING2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56564657; called by muse, mutect2, varscan2
- INHBA | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.309); catalogued as rs1379000367, COSV54221978, COSV54223528; called by muse, mutect2, varscan2
- INHBC | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV59006183; called by muse, mutect2, varscan2
- INPP5D | c.3080C>T p.S1027F (on ENST00000445964 / NM_001017915.3; = p.S1026F on NM_005541.5) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV64035505; called by muse, mutect2, varscan2
- INSL3 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs1228235146, COSV57953774; called by muse, mutect2, varscan2
- INSL4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV53329834, COSV53329980; called by muse, mutect2, varscan2
- INSL6 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs755134539, COSV67563238; called by muse, mutect2, varscan2
- INSRR | c.3301G>A p.D1101N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1231811630, COSV63871976, COSV63877184; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 94/263 reads (36%) | catalogued as rs201715497, COSV63871157; called by muse, mutect2, varscan2
- INSYN2A | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs371917458; called by muse, mutect2, varscan2
- INSYN2A | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV99731880; called by muse, mutect2, varscan2
- INSYN2A | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as rs139810222; called by muse, mutect2, varscan2
2,080 further variants in this file (1,103 protein-altering or splice-affecting, 900 silent, 77 other) are not listed here.
